Somatic mutation profile of tumor specimen MP2PRT-PAPZNW-TMP1-A (aliquot MP2PRT-PAPZNW-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPZNW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.9 years (2,510 days).
Specimen MP2PRT-PAPZNW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4291c222-c5e6-4047-b009-87842d34b3ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPZNW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPZNW-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9c59e7c-5da4-4716-b27d-fee3e23d56f2

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Nonsense Mutation 3, Silent 3, Intron 1, 5'Flank 1, Frame Shift Del 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1700C>T p.P567L (on ENST00000399959; = p.P568L on NM_001356.5) | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519430, CM158051, COSV67863241; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADSS1 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 195/414 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.551); catalogued as rs542898507; called by muse, mutect2, varscan2
- CCDC175 | c.1895dup p.N632Kfs*6 | Frame Shift Ins (INS) | VAF 26/140 reads (19%) | catalogued as rs1198843594; called by mutect2, varscan2
- CLSTN3 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 185/623 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs751373748, COSV56941249; called by muse, mutect2, varscan2
- DDX3X | c.1346C>T p.T449I (on ENST00000399959; = p.T450I on NM_001356.5) | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67863014; called by muse, varscan2
- ERBB4 | c.2512C>T p.R838* | Nonsense Mutation (SNP) | VAF 110/282 reads (39%) | catalogued as rs1423325504, COSV61472598; called by muse, mutect2, varscan2
- FAM189A2 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 169/374 reads (45%) | catalogued as rs1464992721, COSV57385550; called by muse, mutect2, varscan2
- PLD1 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 27/424 reads (6%) | catalogued as rs751346031; called by muse, mutect2
- ARID1B | c.6172_6184del p.G2058Sfs*24 | Frame Shift Del (DEL) | VAF 59/395 reads (15%) | called by mutect2, pindel, varscan2
- FAT4 | c.6194T>C p.I2065T | Missense Mutation (SNP) | VAF 33/422 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2
- FSIP2 | c.15260A>C p.Q5087P | Missense Mutation (SNP) | VAF 95/220 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- MBD2 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 90/480 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OLFML1 | c.686A>T p.N229I | Missense Mutation (SNP) | VAF 134/255 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- OR2A5 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 53/300 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBA2 | c.1366_1371del p.V456_H457del | In Frame Del (DEL) | VAF 29/204 reads (14%) | called by pindel, varscan2
- FAT2 | c.12165C>T p.A4055= | Silent (SNP) | VAF 195/443 reads (44%) | catalogued as rs760967696, COSV55816184; called by muse, mutect2, varscan2
- IGHV1-58 | c.321C>T p.S107= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs911072372; called by muse, varscan2
- MKRN3 | c.258G>A p.P86= | Silent (SNP) | VAF 222/498 reads (45%) | catalogued as rs992964077, COSV100090600, COSV58809496; called by muse, mutect2, varscan2
- ATAD3B | c.282+1720C>T | Intron (SNP) | VAF 10/376 reads (3%) | called by muse, mutect2
- G3BP1 | chr5:151770455 G>C | 5'Flank (SNP) | VAF 254/538 reads (47%) | called by muse, mutect2, varscan2
